Somatic mutation profile of tumor specimen ALCH-AEPK-TTP1-A (aliquot ALCH-AEPK-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AEPK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.6 years (25,431 days).
Specimen ALCH-AEPK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04667f4b-e273-4d37-8596-30300dc187d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEPK-NB1-A (Blood Derived Normal), aliquot ALCH-AEPK-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3167a1db-3c1d-4772-9545-b1d4dfba2702

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 5'UTR 1, Splice Site 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD35 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as rs782613494; called by muse, mutect2
- MTUS2 | c.1140G>C p.E380D | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV70918597; called by muse, mutect2
- SLIT2 | c.4496G>A p.R1499Q | Missense Mutation (SNP) | VAF 19/387 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs142621552, COSV99887093; called by muse, mutect2
- ZNF681 | c.995A>T p.H332L | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1455745060; called by muse, mutect2
- MAGEA12 | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 16/502 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2
- MYCBP2 | c.571C>G p.L191V (on ENST00000357337; = p.L229V on NM_015057.5) | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- NSD2 | c.928-5_928-1delinsTTTTT p.X310_splice | Splice Site (ONP) | VAF 4/45 reads (9%) | called by pindel, varscan2*
- PRDM9 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 24/920 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.035); called by muse, mutect2
- SRGAP1 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 18/302 reads (6%) | called by muse, mutect2
- UGDH | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2
- ZNF600 | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- ARL6IP1 | c.24C>T p.S8= | Silent (SNP) | VAF 9/225 reads (4%) | called by muse, mutect2
- CA1 | c.585C>T p.Y195= | Silent (SNP) | VAF 24/776 reads (3%) | called by muse, mutect2
- INHBE | c.126G>A p.L42= | Silent (SNP) | VAF 61/333 reads (18%) | called by muse, varscan2
- LSM14B | c.*177G>A | 3'UTR (SNP) | VAF 12/350 reads (3%) | called by muse, mutect2
- TFDP2 | c.-11T>C | 5'UTR (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
